Somatic mutation profile of tumor specimen C3N-00737-01 (aliquot CPT0090170010) from CPTAC case C3N-00737, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 71.4 years (26,067 days).
Specimen C3N-00737-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fb5e8d6-c34d-4985-94db-0966562f56f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00737-31 (Blood Derived Normal), aliquot CPT0091440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a8de8dc-7a5e-41c8-a40d-1ea3641c3e45

The open-access MAF lists 245 somatic variants for this specimen: 172 protein-altering or splice-affecting, 43 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 43, Intron 18, Nonsense Mutation 13, Splice Region 6, 3'UTR 6, Splice Site 5, RNA 3, 5'UTR 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs72657697; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 82/351 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3895C>A p.P1299T | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV53979058; called by muse, mutect2
- ADGRG4 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV54965339; called by muse, mutect2, varscan2
- ASXL3 | c.1408C>T p.H470Y | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs866757981, COSV52471458; called by muse, mutect2
- BAIAP2 | c.216C>T p.L72= | Splice Region (SNP) | VAF 25/92 reads (27%) | catalogued as rs757871738; called by muse, mutect2, varscan2
- BCOR | c.1443G>C p.E481D | Missense Mutation (SNP) | VAF 61/541 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs771389229; called by muse, mutect2, varscan2
- BNC1 | c.642G>T p.R214S | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV61756795, COSV99077047; called by muse, mutect2, varscan2
- BRD9 | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 35/393 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs780971767; called by muse, mutect2
- CACNA1B | c.3543C>T p.N1181= | Splice Region (SNP) | VAF 13/69 reads (19%) | catalogued as rs1358025316, COSV99500736; called by muse, mutect2, varscan2
- CD3G | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV99416877; called by muse, mutect2, varscan2
- CHST15 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100655059; called by muse, mutect2
- DCDC1 | c.1646A>G p.N549S | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.834); catalogued as rs376158052; called by muse, varscan2
- DKK4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.368); catalogued as COSV55182383; called by muse, mutect2
- DPY19L4 | c.1643G>A p.R548K | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.63); catalogued as COSV68963673; called by muse, mutect2
- EI24 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV54021531; called by muse, mutect2, varscan2
- ERBB3 | c.3583G>C p.E1195Q | Missense Mutation (SNP) | VAF 90/458 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.301); catalogued as COSV99916314; called by muse, mutect2, varscan2
- FAT4 | c.14185G>A p.D4729N | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV58686704; called by muse, mutect2
- FGF6 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV57403257, COSV99960507; called by muse, mutect2, varscan2
- FNDC5 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750559821; called by muse, mutect2, varscan2
- GAGE2A | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 159/1060 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62995513; called by muse, mutect2, varscan2
- GRK7 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV53825114; called by muse, mutect2
- GTF3C1 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62240615, COSV62243550; called by muse, mutect2, varscan2
- HCN1 | c.2476G>T p.G826C | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs1262369935, COSV100300925; called by muse, mutect2
- HERC2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 22/141 reads (16%) | catalogued as COSV99876015; called by muse, mutect2, varscan2
- HFM1 | c.3718C>T p.Q1240* | Nonsense Mutation (SNP) | VAF 18/205 reads (9%) | catalogued as rs866263287; called by muse, mutect2
- IFT172 | c.2421C>G p.I807M | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs367649864; called by muse, mutect2, varscan2
- IQGAP1 | c.3091C>T p.Q1031* | Nonsense Mutation (SNP) | VAF 17/165 reads (10%) | catalogued as COSV51586433; called by muse, mutect2, varscan2
- ITGA6 | c.3352C>A p.Q1118K (on ENST00000442250; = p.Q1079K on NM_001079818.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.412); catalogued as rs1277446129; called by muse, mutect2, varscan2
- KDM6B | c.4480C>T p.Q1494* | Nonsense Mutation (SNP) | VAF 35/604 reads (6%) | catalogued as COSV99642510; called by muse, mutect2
- KIAA1210 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs934680222, COSV68177088; called by muse, mutect2, varscan2
- LARGE1 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.034); catalogued as COSV61660710; called by muse, mutect2, varscan2
- MCM3AP | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1223196433; called by muse, mutect2, varscan2
- MICAL3 | c.2801+8C>T | Splice Region (SNP) | VAF 12/130 reads (9%) | catalogued as rs187724588; called by muse, mutect2
- MIS18BP1 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs1454733946; called by muse, mutect2
- MTDH | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs779147254, COSV100292232; called by muse, mutect2, varscan2
- MTMR8 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1419669011; called by muse, varscan2
- MUC5B | c.11888C>T p.P3963L | Missense Mutation (SNP) | VAF 70/882 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1183700496; called by muse, mutect2
- MYH15 | c.4283G>C p.R1428T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs760289290; called by muse, mutect2
- MYH15 | c.559C>A p.R187= | Splice Region (SNP) | VAF 65/264 reads (25%) | catalogued as COSV56312226, COSV99842572; called by muse, mutect2, varscan2
- NAT8 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV55542883; called by muse, mutect2
- NAV3 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs776928962, COSV57097401; called by muse, mutect2, varscan2
- NCOA3 | c.2870C>G p.S957C | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs778964948; called by muse, mutect2
- OBSL1 | c.1689G>C p.W563C | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346848867; called by muse, mutect2, varscan2
- OGFOD2 | c.403+3G>A | Splice Region (SNP) | VAF 67/256 reads (26%) | catalogued as rs1192573255; called by muse, mutect2, varscan2
- OR5D13 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs561869024; called by muse, mutect2, varscan2
- OR5H2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV62350238; called by muse, mutect2, varscan2
- OR5T3 | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57379423; called by muse, mutect2, varscan2
- OTOG | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs574498870, COSV100696101; called by muse, mutect2, varscan2
- PCDH10 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 28/228 reads (12%) | catalogued as rs766732233, COSV52098110; called by muse, mutect2, varscan2
- PCDHB12 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.013); catalogued as COSV99506488; called by muse, mutect2, varscan2
- PDE8B | c.2140C>G p.R714G | Missense Mutation (SNP) | VAF 52/488 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53740810; called by muse, mutect2, varscan2
- PEAK1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.156); catalogued as COSV56933184; called by mutect2, varscan2
- PKD1L1 | c.2951C>T p.T984M | Missense Mutation (SNP) | VAF 59/437 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs764115525, COSV99220550; called by muse, mutect2, varscan2
- PRDM11 | c.84C>A p.Y28* | Nonsense Mutation (SNP) | VAF 21/191 reads (11%) | catalogued as rs1199931506; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.340G>A p.E114K (on ENST00000421990 / NM_001136042.2; = p.E96K on NM_025267.3) | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.569); catalogued as rs1295592694, COSV64182624; called by muse, mutect2, varscan2
- RB1 | c.861+1G>A p.X287_splice | Splice Site (SNP) | VAF 47/201 reads (23%) | catalogued as CS0910389, COSV57298588, COSV57307382; called by muse, mutect2, varscan2
- SH3PXD2B | c.1061T>C p.I354T | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs764014429; called by muse, mutect2
- SLC35F2 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs201112675; called by muse, mutect2, varscan2
- SLC44A5 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1473846869; called by muse, mutect2, varscan2
- SLC47A1 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs138902371; called by muse, mutect2, varscan2
- SPAG9 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV56244453; called by muse, mutect2, varscan2
- SUCNR1 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 72/347 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62912504; called by muse, mutect2, varscan2
- TBC1D20 | c.747G>T p.M249I | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV62612981; called by muse, mutect2, varscan2
- TMCC1 | c.1113G>C p.E371D (on ENST00000393238 / NM_001349268.2; = p.E47D on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as COSV100260702; called by muse, mutect2, varscan2
- TNXB | c.8515G>C p.G2839R (on ENST00000647633; = p.G2592R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767643312, CM164301, COSV64476969; called by muse, mutect2, varscan2
- TRIML2 | c.979G>C p.A327P | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV58714944, COSV58718997; called by muse, mutect2, varscan2
- UNC13D | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768171054, CM066255, COSV99257864; called by muse, mutect2
- USP38 | c.3061G>C p.G1021R | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755211360, COSV61024748; called by muse, mutect2, varscan2
- ZNF611 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as COSV60539981; called by muse, mutect2
- AATK | c.3240_3283del p.P1081Qfs*21 (on ENST00000326724 / NM_001080395.3; = p.P978Qfs*21 on NM_004920.2) | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel
- ACCSL | c.4A>T p.S2C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKIB1 | c.818G>C p.W273S | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARAF | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ARHGAP32 | c.3232G>T p.A1078S (on ENST00000310343 / NM_001378025.1; = p.A729S on NM_014715.4) | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); called by muse, mutect2
- ASPM | c.4065+2T>A p.X1355_splice | Splice Site (SNP) | VAF 31/183 reads (17%) | called by muse, mutect2, varscan2
- ATR | c.7744G>C p.E2582Q | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AVL9 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- BAZ1B | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- BHLHE22 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- BMP15 | c.293T>A p.V98E | Missense Mutation (SNP) | VAF 95/167 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CADPS2 | c.3472-2A>C p.X1158_splice | Splice Site (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- CD48 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 45/405 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CEP135 | c.2633A>G p.D878G | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CILP | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CLHC1 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2
- CLHC1 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- CNBD2 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CPA4 | c.191T>A p.V64E | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CPSF1 | c.1294+1G>C p.X432_splice | Splice Site (SNP) | VAF 11/234 reads (5%) | called by muse, mutect2
- DCTN1 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- DPY19L3 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 78/341 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2B5 | c.1561A>T p.N521Y (on ENST00000647909; = p.N513Y on NM_003907.3) | Missense Mutation (SNP) | VAF 52/628 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2
- EIF3A | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EIF4G1 | c.2575G>T p.E859* (on ENST00000346169 / NM_198241.3; = p.E664* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 149/700 reads (21%) | called by muse, mutect2, varscan2
- EPHA4 | c.2603G>A p.R868K | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.6263C>A p.T2088N | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, varscan2
- FASLG | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 56/529 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, varscan2
- FAT3 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.251); called by muse, mutect2
- FBXO46 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FCAR | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 90/537 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FRMPD1 | c.3434C>T p.S1145L | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR156 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); called by muse, varscan2
- GPR156 | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- HSPA1L | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HSPBAP1 | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 62/389 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ICA1 | c.762G>C p.E254D | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- IFIT3 | c.520T>A p.S174T | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IFT122 | c.1627A>G p.I543V (on ENST00000348417 / NM_052989.3; = p.I484V on NM_018262.4) | Missense Mutation (SNP) | VAF 47/579 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- IL7R | c.801-8G>C | Splice Region (SNP) | VAF 17/438 reads (4%) | called by muse, mutect2
- INTU | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 49/608 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.232); called by muse, mutect2
- ITGA2B | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNK16 | c.11C>A p.A4D | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KCNQ2 | c.1282T>G p.C428G | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); called by muse, mutect2
- KDM5B | c.3047G>C p.R1016T | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- KIF21B | c.2705A>G p.K902R | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KRT38 | c.1187G>C p.R396P | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- LAMA2 | c.5024C>A p.A1675E | Missense Mutation (SNP) | VAF 111/526 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2
- LOXHD1 | c.6117G>T p.E2039D (on ENST00000642948; = p.E1977D on NM_144612.7) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.395); called by muse, mutect2
- LRP1B | c.7472G>T p.C2491F | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP3K2 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPKBP1 | c.858C>G p.I286M (on ENST00000456763 / NM_001128608.2; = p.I280M on NM_014994.3) | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, varscan2
- MAPKBP1 | c.923C>G p.S308C (on ENST00000456763 / NM_001128608.2; = p.S302C on NM_014994.3) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- MB21D2 | c.1118T>G p.M373R | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MCM4 | c.2239G>C p.V747L | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MFN1 | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- MMS22L | c.1634A>T p.E545V | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- NALCN | c.3334C>A p.L1112I | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NEIL3 | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2
- NLRP8 | c.782A>T p.E261V | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- OR5T3 | c.516A>G p.I172M | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR7D4 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PCDHA11 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCD11 | c.4634C>G p.S1545C | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PDIA6 | c.407A>T p.K136M | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIEZO2 | c.6958G>A p.G2320R | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRDM11 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTDSS2 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAD51AP2 | c.2722G>C p.E908Q | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, varscan2
- RAD51AP2 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, varscan2
- RASA2 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- RNF141 | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 15/215 reads (7%) | called by muse, mutect2
- SCN1A | c.5134A>C p.N1712H (on ENST00000303395 / NM_001202435.3; = p.N1701H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETDB1 | c.3860G>C p.R1287T (on ENST00000271640 / NM_001366417.1; = p.R1286T on NM_012432.4) | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- SGSM1 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRN3 | c.1907C>T p.S636L (on ENST00000357479 / NM_001083893.2; = p.S552L on NM_014574.4) | Missense Mutation (SNP) | VAF 148/358 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SYNE1 | c.15487G>C p.E5163Q (on ENST00000367255 / NM_182961.4; = p.E5092Q on NM_033071.3) | Missense Mutation (SNP) | VAF 56/530 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2
- SYTL2 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.034); called by muse, mutect2
- TATDN2 | c.688C>G p.P230A | Missense Mutation (SNP) | VAF 122/474 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TBX22 | c.894C>A p.Y298* | Nonsense Mutation (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- THEGL | c.1157T>G p.L386R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- TIAM2 | c.1708G>T p.A570S | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM150B | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.037); called by muse, varscan2
- TMEM200A | c.1405A>T p.N469Y | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM217 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNRC6A | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 92/529 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TPO | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TRIM47 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TRMT2A | c.1360G>C p.V454L | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- TTC27 | c.1887G>A p.W629* | Nonsense Mutation (SNP) | VAF 38/229 reads (17%) | called by muse, mutect2, varscan2
- URB2 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- USH2A | c.3865A>T p.T1289S | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- VNN1 | c.131T>G p.V44G | Missense Mutation (SNP) | VAF 11/329 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- VPS4B | c.873-1G>C p.X291_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- ZDBF2 | c.7052A>G p.N2351S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZMPSTE24 | c.1401A>T p.Q467H | Missense Mutation (SNP) | VAF 37/751 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); called by muse, mutect2
- ZMYM4 | c.4029G>C p.L1343F | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ZNF280B | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ZNF33A | c.517G>A p.G173R (on ENST00000458705 / NM_006974.3; = p.G174R on NM_006954.2) | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.132); called by muse, mutect2
- ZNF583 | c.1600C>A p.H534N | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ZSCAN5C | c.1402C>A p.H468N | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABCB1 | c.3540G>A p.Q1180= | Silent (SNP) | VAF 99/423 reads (23%) | catalogued as COSV55963422; called by muse, mutect2, varscan2
- AC009779.3 | c.123G>A p.Q41= | Silent (SNP) | VAF 64/236 reads (27%) | catalogued as COSV57726437; called by muse, varscan2
- ADAM23 | c.2379C>G p.L793= | Silent (SNP) | VAF 54/212 reads (25%) | called by muse, mutect2, varscan2
- ANK2 | c.1734G>T p.V578= | Silent (SNP) | VAF 54/411 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.1083C>T p.P361= | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as rs773769674, COSV56320360; called by muse, mutect2, varscan2
- BRIP1 | c.1035G>A p.K345= | Silent (SNP) | VAF 72/636 reads (11%) | catalogued as COSV104386499; called by muse, mutect2, varscan2
- C19orf47 | c.306C>G p.L102= | Silent (SNP) | VAF 33/270 reads (12%) | called by muse, mutect2, varscan2
- CCHCR1 | c.1002G>A p.L334= | Silent (SNP) | VAF 29/339 reads (9%) | catalogued as COSV66182581; called by muse, mutect2
- CD84 | c.999T>C p.S333= (on ENST00000311224 / NM_001184879.2; = p.S316= on NM_003874.4) | Silent (SNP) | VAF 28/390 reads (7%) | called by muse, mutect2
- CFAP69 | c.1008G>A p.L336= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV60185866, COSV60188997; called by muse, mutect2, varscan2
- CHD6 | c.6555G>A p.V2185= | Silent (SNP) | VAF 45/172 reads (26%) | catalogued as rs762620699; called by muse, varscan2
- COL11A1 | c.2898G>T p.G966= | Silent (SNP) | VAF 30/354 reads (8%) | catalogued as COSV62176390; called by muse, mutect2
- COL4A2 | c.1263C>T p.Y421= | Silent (SNP) | VAF 67/271 reads (25%) | catalogued as rs757264758, COSV64628302; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.7119C>T p.S2373= | Silent (SNP) | VAF 117/466 reads (25%) | called by muse, mutect2, varscan2
- CTCFL | c.1419C>G p.L473= | Silent (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- EYS | c.6264C>A p.T2088= | Silent (SNP) | VAF 24/192 reads (13%) | called by muse, varscan2
- F8 | c.5847T>A p.P1949= | Silent (SNP) | VAF 26/147 reads (18%) | called by muse, varscan2
- FOLR2 | c.369C>T p.F123= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs771923158; called by muse, mutect2
- GRIA2 | c.1599A>G p.P533= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as rs1201584662; called by muse, mutect2
- H3C13 | c.27C>T p.R9= | Silent (SNP) | VAF 114/351 reads (32%) | catalogued as COSV100516011, COSV58944970; called by muse, mutect2, varscan2
- HEG1 | c.1689A>G p.K563= | Silent (SNP) | VAF 51/371 reads (14%) | catalogued as rs1343920209; called by muse, mutect2, varscan2
- HSD17B7 | c.471C>G p.L157= | Silent (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2
- ITPRIPL2 | c.1119C>G p.L373= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- JAK3 | c.2829C>T p.R943= | Silent (SNP) | VAF 25/219 reads (11%) | called by muse, mutect2, varscan2
- OR10A2 | c.705C>A p.V235= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as COSV100225201, COSV56300446; called by muse, mutect2, varscan2
- OR4S2 | c.478C>T p.L160= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV56745513, COSV99044723; called by muse, mutect2, varscan2
- PCDH15 | c.4899A>G p.S1633= | Silent (SNP) | VAF 114/479 reads (24%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.1950C>G p.L650= | Silent (SNP) | VAF 50/234 reads (21%) | called by muse, mutect2, varscan2
- PLAGL1 | c.624A>G p.S208= | Silent (SNP) | VAF 38/440 reads (9%) | called by muse, mutect2
- RTN1 | c.525C>G p.S175= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV99955316; called by muse, mutect2, varscan2
- RTN2 | c.12C>A p.V4= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs1355479472; called by muse, mutect2
- SEZ6L | c.576G>T p.A192= | Silent (SNP) | VAF 68/251 reads (27%) | catalogued as rs368342681, COSV99962566; called by muse, mutect2, varscan2
- SFMBT2 | c.2070G>A p.R690= | Silent (SNP) | VAF 58/246 reads (24%) | called by muse, mutect2, varscan2
- SLC13A1 | c.1761T>C p.P587= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- SOX8 | c.1167C>T p.S389= | Silent (SNP) | VAF 69/240 reads (29%) | catalogued as rs756292394; called by muse, mutect2, varscan2
- SPATA31E1 | c.2088C>T p.F696= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as rs755678672; called by muse, mutect2, varscan2
- SPDYE5 | c.795C>G p.S265= | Silent (SNP) | VAF 49/451 reads (11%) | called by muse, mutect2, varscan2
- SRPRA | c.1591C>T p.L531= | Silent (SNP) | VAF 24/224 reads (11%) | catalogued as COSV99703053; called by muse, mutect2
- TERT | c.516G>C p.G172= | Silent (SNP) | VAF 27/330 reads (8%) | called by muse, mutect2
- UACA | c.1797A>G p.E599= | Silent (SNP) | VAF 46/232 reads (20%) | called by muse, mutect2, varscan2
- WNT4 | c.42C>A p.V14= | Silent (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- ZSCAN12 | c.933C>T p.F311= | Silent (SNP) | VAF 16/223 reads (7%) | catalogued as rs1405858411; called by muse, mutect2
- ZZZ3 | c.2625A>G p.S875= | Silent (SNP) | VAF 16/165 reads (10%) | called by muse, mutect2, varscan2
- AARS1 | c.2287-45T>A | Intron (SNP) | VAF 41/275 reads (15%) | called by muse, mutect2, varscan2
- AC004951.2 | n.120dup | RNA (INS) | VAF 38/210 reads (18%) | called by mutect2, varscan2
- AC006486.1 | c.23-3052C>A | Intron (SNP) | VAF 25/239 reads (10%) | called by muse, mutect2, varscan2
- AC084879.1 | n.1172C>T | RNA (SNP) | VAF 43/360 reads (12%) | called by muse, mutect2, varscan2
- ADAM22 | c.2408+30C>T | Intron (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2, varscan2
- AGTR1 | c.*32G>T | 3'UTR (SNP) | VAF 40/548 reads (7%) | called by muse, mutect2
- C2CD6 | c.1581+3767A>G | Intron (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- CENPT | c.863-92G>C | Intron (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- COL4A2 | c.1340-489T>C | Intron (SNP) | VAF 218/1077 reads (20%) | catalogued as rs1399813904; called by muse, varscan2
- EIF2AK1 | c.*12A>T | 3'UTR (SNP) | VAF 27/329 reads (8%) | called by muse, mutect2
- ELFN1 | c.-456+5463A>G | Intron (SNP) | VAF 40/414 reads (10%) | called by muse, mutect2
- FUT7 | chr9:137034972 C>G | 5'Flank (SNP) | VAF 53/248 reads (21%) | called by muse, mutect2, varscan2
- GP6 | c.*155G>A | 3'UTR (SNP) | VAF 78/384 reads (20%) | called by muse, mutect2, varscan2
- GYS1 | c.*534A>T | 3'UTR (SNP) | VAF 45/431 reads (10%) | called by muse, mutect2, varscan2
- JAG1 | c.756-37C>G | Intron (SNP) | VAF 30/272 reads (11%) | called by muse, mutect2, varscan2
- LINC01621 | n.1216G>C | RNA (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- LMTK3 | c.*44G>C | 3'UTR (SNP) | VAF 37/195 reads (19%) | called by muse, mutect2, varscan2
- MROH8 | c.-321G>A | 5'UTR (SNP) | VAF 29/229 reads (13%) | called by muse, mutect2, varscan2
- MSX1 | c.470-132G>A | Intron (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- NPHP4 | c.2611+581G>A | Intron (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- PA2G4 | c.324-12C>T | Intron (SNP) | VAF 50/230 reads (22%) | called by muse, mutect2, varscan2
- PAH | c.-6G>A | 5'UTR (SNP) | VAF 135/467 reads (29%) | catalogued as COSV61021154; called by muse, mutect2, varscan2
- PPM1N | c.939+243T>G | Intron (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- PRSS40A | n.317+52G>C | Intron (SNP) | VAF 23/372 reads (6%) | catalogued as rs1348299965; called by muse, mutect2
- RYR2 | c.11146-1173C>T | Intron (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- SDHAF2 | c.36+43G>T | Intron (SNP) | VAF 25/218 reads (11%) | called by muse, mutect2, varscan2
- SGSM2 | c.1653+27C>G | Intron (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- SMAD3 | c.207-26812A>G | Intron (SNP) | VAF 27/246 reads (11%) | called by muse, mutect2, varscan2
- TMEM67 | c.406+1396T>C | Intron (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- ZNFX1 | c.*342T>C | 3'UTR (SNP) | VAF 28/66 reads (42%) | catalogued as rs772055435; called by muse, mutect2
